Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2CU, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2CU-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient
Name:
MRN:
DOB:
Gender: F
HCN:
Ordering
MD:
Copy To:

Service:
Visit #:
Location:
Facility:

Accession #:
Collected:
Received:
Reported:

Specimen(s) Received

1. Soft-Tissue: Query right inferior parathyroid
2. Lymph node: Left paratracheal node
3. Thyroid: Total thyroid stitch left superior pole
4. Lymph node: Right paratracheal node

Reviewed Initials:	KMM	6/18/11

Diagnosis

1. No pathological diagnosis: Parathyroid (right inferior) biopsy
2. No pathological diagnosis: Lymph nodes, 4 (left paratracheal) biopsy
3. Papillary carcinoma, follicular variant, right, 4.0 cm; underlying focal chronic thyroiditis: Thyroid
Metastatic papillary thyroid carcinoma: Lymph nodes, 3 of 23 central compartment
No pathological diagnosis: Lymph nodes, 1, isthmic, 1 left perithyroidal
No pathological diagnosis: Parathyroids, 2, right perithyroidal and left central compartment
- total thyroidectomy specimen
4. Metastatic papillary thyroid carcinoma: Lymph node, 1 (right paratracheal) excisional biopsy

Synoptic Data

Procedure:
Received:
Specimen Integrity:
Specimen Size:

Total thyroidectomy with central compartment dissection
Fresh
Intact
Right lobe: 1CD-0-3
4.2 cm
3.3 cm
2.2 cm
Left lobe:
3.6 cm
2.3 cm
1.0 cm

carcinoma, papillary, follicular variant
8340/3

Site: thyroid, NOS C73.9 6/18/11

[page 2 of 3]
	Isthmus +/- pyramidal lobe:
	1.2 cm
	1.2 cm
	0.6 cm
	Central compartment:
	4.8 cm
	1.6 cm
	1.2 cm
Specimen Weight:	28.7 g
Tumor Focality:	Unifocal
----- DOMINANT TUMOR -----	
Tumor Laterality:	Right Lobes
Tumor Size:	Greatest dimension: 4.0cm
	Additional dimension: 2.8 cm
	Additional dimension: 1.7 cm
Histologic Type:	Papillary carcinoma, follicular variant per TSS, follicular variant = 100% Follicular architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pN1a: Nodal metastases to Level VI (pretracheal, paratracheal and prelaryngeal/Delphian) lymph nodes Number of regional lymph nodes examined: 30 Number of regional lymph nodes involved: 4 Lymph Node, Extranodal Extension Not identified
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Thyroiditis, focal (nonspecific)

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

verified by:

Electronically

Gross Description

1. The specimen labeled with the patient's name and as "Soft Tissue: Query right inferior parathyroid" consists of a piece of fibrous tissue that measures 0.1 x 0.1 cm. It is frozen for intraoperative consultation.

1A frozen section block resubmitted

[page 3 of 3]
2. The specimen labeled with the patient's name and as "Lymph Node: Left paratracheal node" consists of two fragments of red-yellow fatty tissue measuring 1.2 x 0.5 x 0.5 cm and 1.4 x 0.7 x 0.5 cm.

2A submitted in toto.

3. The specimen labeled with the patient's name and as "Thyroid: Total thyroid stitch left superior pole" consists of a thyroid gland that is oriented with a stitch and weighs 28.7 g. The right lobe measures 4.2 cm SI x 3.3 cm ML x 2.2 cm AP, the left lobe measures 3.6 cm SI x 2.3 cm ML x 1.0 cm AP and the isthmus measures 1.2 cm SI x 1.2 cm ML x 0.6 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands are identified grossly. Attached to the inferior aspect of the left lobe is the central compartment contents that measure 4.8 x 1.6 x 1.2 cm and contain multiple lymph nodes ranging in size from 0.4 cm to 0.8 cm. The external surface is painted with Silver nitrate. The right lobe contains a well delineated nodule that measures 4.0 cm SI x 2.8 cm ML x 1.7 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of right lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

3A-J right lobe, superior to inferior

3K-L isthmus

3M-R left lobe, superior to inferior

3S-T multiple lymph nodes each block

3U-V fatty tissue attached to the inferior aspect of the left lobe in toto.

4. The specimen labeled with the patient's name and as "Lymph Node: Right paratracheal node" consists of a nodule with attached fatty tissue measuring 3.2 x 2.6 x 1.7 cm received in 10% buffered formalin.

4A-E submitted in toto.

Quick Section Diagnosis

1A – parathyroid tissue. Reported to

Source: NCI Genomic Data Commons file e50fd804-5fdb-4fd6-872e-4be06860f725 (TCGA-EM-A2CU.77194F16-66D9-4D4F-B111-0AC53989F6DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).